Gene-level copy-number profile of tumor specimen TCGA-DZ-6131-01A from TCGA case TCGA-DZ-6131, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 31.4 years (11,487 days).
Specimen TCGA-DZ-6131-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.417cab0f-6b84-4521-8b9c-bb43d2dc6dbf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DZ-6131-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/27d308b0-c109-4f2e-b6db-0044855832fc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 27; copy number 2: 4,024; copy number 3: 12,386; copy number 4: 41,220; copy number 5: 1,053; copy number 6: 1,076; copy number 7: 8; copy number 8: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DZ-6131-01A-11D-1959-01): tumor purity 0.76, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:60,021,249–60,548,813, 8 genes: AC034234.1, RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1.
- chr9:21,929,457–21,995,301, 3 genes: ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
